Somatic mutation profile of tumor specimen TARGET-10-PASUIN-09A (aliquot TARGET-10-PASUIN-09A-01D) from TARGET case TARGET-10-PASUIN, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.7 years (5,004 days).
Specimen TARGET-10-PASUIN-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4345f81a-8bd0-4a4c-8351-855d64ea6cc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASUIN-10A (Blood Derived Normal), aliquot TARGET-10-PASUIN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40566005-0561-4a0a-92db-1007201a5492

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, RNA 1, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1, Intron 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL14A1 | c.2930T>C p.L977P | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52849503; called by muse, mutect2, varscan2
- COL1A2 | c.4012C>T p.R1338C | Missense Mutation (SNP) | VAF 74/163 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781721538, COSV51953052; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX57 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as COSV54883266; called by muse, mutect2, varscan2
- EIF4A1 | c.17A>T p.D6V | Missense Mutation (SNP) | VAF 78/170 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV53442369; called by muse, varscan2
- EPHA7 | c.2899G>A p.G967R | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs560174275, COSV65178891, COSV65192034; called by muse, mutect2, varscan2
- FOXP1 | c.959T>C p.F320S | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV59537277; called by muse, mutect2, varscan2
- IL36RN | c.72C>G p.N24K | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as COSV61010380; called by muse, mutect2, varscan2
- LCOR | c.2540T>C p.V847A | Missense Mutation (SNP) | VAF 89/173 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV53714930; called by muse, mutect2, varscan2
- LRRC4B | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65349464; called by muse, mutect2, varscan2
- NOTCH1 | c.4721T>C p.L1574P | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53024760, COSV53072929; called by muse, mutect2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- RSPO2 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 20/41 reads (49%) | catalogued as COSV52640252; called by muse, mutect2, varscan2
- SLC12A7 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV53755330, COSV53759589; called by muse, mutect2, varscan2
- ZFYVE19 | c.404G>A p.G135E (on ENST00000355341 / NM_001077268.2; = p.G125E on NM_032850.5) | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as COSV54539538; called by muse, mutect2, varscan2
- HSPA4 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- PPP4R3C | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 40/40 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- ANKRD27 | c.1617C>T p.Y539= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs766636078, COSV60135768; called by muse, mutect2, varscan2
- ANKRD52 | c.2211G>A p.L737= | Silent (SNP) | VAF 48/92 reads (52%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.642C>T p.N214= | Silent (SNP) | VAF 17/182 reads (9%) | catalogued as rs377539827; called by muse, mutect2
- ANO5 | c.-156_-155insAGGGGAATGAGGAGGAGGAGGACG | 5'UTR (INS) | VAF 13/38 reads (34%) | called by mutect2, varscan2*
- C10orf71 | c.*44C>G | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010176 A>C | 5'Flank (SNP) | VAF 73/179 reads (41%) | called by muse, mutect2, varscan2
- MSL3P1 | n.1285delinsACCCCCTGCGGTCCCTCTCTCCC | RNA (INS) | VAF 19/59 reads (32%) | called by pindel, varscan2*
- RBL2 | c.1864-81T>A | Intron (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
